Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4345, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4345-01A (Primary Tumor).

[page 1 of 4]
.....

Clinical Diagnosis & History:

██████████ with right renal mass.

Specimens Submitted:

- 1: Kidney, right; radical nephrectomy
- 2: Lymph nodes, paracaval; excision
- 3: Right adrenal and supra-hilar lymph nodes; adrenalectomy and lymphadenectomy ██████████

AMENDED DIAGNOSIS:

1. Kidney, right; radical nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 5.5 cm.

Local Invasion (for renal cortical types):

Involves renal sinus fat

Renal Vein Invasion:

Not identified

Tumor involves a large vein in the renal sinus

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Chronic inflammation and focal fibrosis

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

[page 2 of 4]
[REDACTED]

SURGICAL PATHOLOGY REPORT

2. Lymph nodes, paracaval; excision:

Lymph Nodes:

Not involved

Number of nodes examined:1

3. Right adrenal and supra-hilar lymph nodes; adrenalectomy and lymphadenectomy [REDACTED]

Adrenal gland; no tumor identified

No lymph nodes identified within fibroadipose tissue

Note:

This document represents an amended version of the surgical pathology report originally issued on [REDACTED]. That report is superseded by the present document. The amendment consists of the following change:

ORIGINAL REPORT:

Specimen Submitted:

1: Kidney, right; partial nephrectomy

Final Diagnosis:

1: Kidney, right; partial nephrectomy

AMENDED REPORT:

Specimen Submitted:

1: Kidney, right; radical nephrectomy

Final Diagnosis:

1: Kidney, right; radical nephrectomy

The responsible clinician has been notified.

[REDACTED]

[REDACTED]

Gross Description:

[REDACTED]

1). The specimen is received fresh labeled "right kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 530 g in total. The kidney measures 10.9 x 5.4 x 4.7 cm. The attached ureter measures 4 cm in length and 0.3 cm in diameter. The attached renal vein measures 0.5 cm in length and 0.7 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is not identified. The kidney is inked black and bivalved to reveal lobulated, well defined tumor with an orange/tan and focally hemorrhagic appearance, measuring 5.5 x 4.7 x 4.3 cm, located in the mid and lower pole of the kidney. The tumor does not grossly extend to the inked margin, and is located at 0.4 cm from the inked surface. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 2.2 cm and the calyces appear normal. Possible lymph nodes are identified in the perinephric fat. Representative sections are submitted for [REDACTED] and for permanent sections.

Summary of sections:

UVM -- ureteral and vessel margins

T-- tumor

THF-- tumor with hilar fat

TSF -- tumor with sinus fat

TK -- tumor with adjacent kidney

RP -- renal pelvis representative sections

K -- representative sections kidney

LNN -possible lymph node [REDACTED]

2). The specimen is received in formalin, labeled "paracaval lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.3 to 1.5 cm in greatest dimension. All identified lymph nodes are submitted.

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

Summary of sections:

LN -- lymph nodes

BLN-- bisected lymph nodes

3). The specimen is received in formalin, labeled "right adrenal and supra-hilar lymph nodes" and consists of a nodular, adrenal gland measuring 3.5 x 2.8 and 1.5 centimeters with attached fibroadipose tissue. Cut section of the gland reveals a well-delineated orange/tan nodular appearance with areas of hemorrhage. No lymph nodes are identified in the attached soft tissues. Representative sections of the adrenal gland and possible lymph nodes are submitted for permanent section.

Summary of sections:

A-adrenal gland

Ln-possible lymph nodes

Summary of Sections:

Part 1: Kidney, right; radical nephrectomy

Block	Sect. Site	PCs
1	k	1
4	lnn	4
1	rp	1
4	t	4
1	thf	1
1	tk	1
1	tsf	1
1	uvm	1

Part 2: Lymph nodes, paracaval; excision

Block	Sect. Site	PCs
1	bln	1
2	ln	2

Part 3: Right adrenal and supra-hilar lymph nodes; adrenalectomy and lymphadenectomy

Block	Sect. Site	PCs
3	a	3
1	ln	1

Amendments

Original Diagnosis:

1. Kidney, right; partial nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 5.5 cm.

Local Invasion (for renal cortical types):

Involves renal sinus fat

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Renal Vein Invasion:

Not identified

Tumor involves a large vein in the renal sinus

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Chronic inflammation and focal fibrosis

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

2. Lymph nodes, paracaval; excision:

Lymph Nodes:

Not involved

Number of nodes examined:1

4. Right adrenal and supra-hilar lymph nodes; adrenalectomy and lymphadenectomy (

Adrenal gland; no tumor identified

No lymph nodes identified within fibroadipose tissue

Source: NCI Genomic Data Commons file 5eb879d6-c9c4-423d-8332-29c664d80042 (TCGA-BP-4345.E771BFDB-94BD-49ED-B8F6-5DD0AF4345DA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).